Somatic mutation profile of tumor specimen C3L-00010-01 (aliquot CPT0001220165) from CPTAC case C3L-00010, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 30.2 years (11,025 days).
Specimen C3L-00010-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea4f7d95-3d56-42b6-9272-dc863d6c1b3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00010-31 (Blood Derived Normal), aliquot CPT0000060163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/269ca5e4-443a-4925-ba9d-5b95f83a102c

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 2, Intron 1, 3'UTR 1, RNA 1, Silent 1, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 120/443 reads (27%) | hotspot (GDC flag); catalogued as rs5030818, CM941381, CM961432, COSV56542817, COSV56554019, COSV56564848; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CHID1 | c.-44+8C>T | Splice Region (SNP) | VAF 8/34 reads (24%) | catalogued as rs997651825; called by muse, varscan2
- IL32 | c.203T>C p.I68T (on ENST00000396890 / NM_001308078.4; = p.I22T on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs748365535; called by muse, mutect2, varscan2
- KDM5C | c.42C>G p.C14W | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62890990; called by muse, mutect2, varscan2
- MPP4 | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760552079; called by muse, mutect2, varscan2
- WFS1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 104/390 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.04); catalogued as rs769712303; called by muse, mutect2, varscan2
- COL4A2 | c.4345C>T p.P1449S | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ERGIC3 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- INMT | c.555_556del p.L186Afs*24 | Frame Shift Del (DEL) | VAF 55/264 reads (21%) | called by mutect2, pindel, varscan2
- KCNH2 | c.2513T>A p.L838Q | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO1E | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 13/269 reads (5%) | called by muse, mutect2
- TOR3A | c.723C>A p.H241Q | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZFP91 | c.731dup p.P246Afs*18 | Frame Shift Ins (INS) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- ZNF81 | c.830C>A p.T277N | Missense Mutation (SNP) | VAF 156/380 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DST | c.14170T>C p.L4724= (on ENST00000361203 / NM_001374722.1; = p.L2312= on NM_015548.5) | Silent (SNP) | VAF 36/150 reads (24%) | called by muse, varscan2
- IGFN1 | c.1242-941C>T | Intron (SNP) | VAF 42/144 reads (29%) | called by muse, mutect2, varscan2
- PRR27 | n.326C>T | RNA (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- XIRP2 | c.*318G>C | 3'UTR (SNP) | VAF 41/187 reads (22%) | catalogued as COSV54704785; called by muse, mutect2, varscan2
